Surgical pathology report (de-identified scan), TCGA case TCGA-SN-A6IS, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site BLN - Baylor, specimen TCGA-SN-A6IS-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD-0-3
Tumor, germ cell
mixed 9085/3
Site @ Testis NOS
C62.9
QW 6/20/13

PATHOLOGIC DIAGNOSIS

RIGHT TESTICLE, RADICAL ORCHIECTOMY:

- MIXED GERM CELL TUMOR
- 85% SEMINOMA (CLASSIC TYPE) AND 15% MATURE TERATOMA (SEE MICRO)
- 7 CM IN THE LARGEST DIMENSION
- TUMOR INVADES TUNICA ALBUGINEA, BUT NOT VAGINALIS
- NO PERINEURAL OR LYMPHOVASCULAR INVASION
- NEGATIVE SPERMATIC CORD MARGIN
- INTRATUBULAR GERM CELL NEOPLASIA (ITGCN)

Tumor Staging (Pathology)

Anatomic site of cancer: Right testis Pre-Orchiectomy

Serum Tumor Markers:

Histologic type: Mixed germ cell tumor - AFP: 3.3
ng/mL (0.0-8.0 ng/mL)

Tumor size (cm): 7 cm in the largest dimension - LDH:
240 U/L (84-246 U/L)

Primary tumor (T): pT1 - hCG: 1708 mIU/mL
(0-1 mIU/mL)

Lymph node (N): pNX

Serum tumor markers (S): S1

Distant metastasis (M): MX

Site of distant metastasis: Not known

Surgical margins: Free

Comment: The findings were communicated via email with and
Urology Department at on

Staff Pathologist

Pertinent Clinical Information

Pertinent history: A HM with testicular mass (right).

Gross Description

Specimen Material: Right testicle.

[page 2 of 2]
Received fresh for tumor banking and labeled "RIGHT TESTICLE," is 81.0 grams, 7.0 x 4.5 x 3.0 cm right testicle with 8.0 cm in length and 1.2 x 0.4 cm cut surface attached spermatic cord. The tunica vaginalis is present and is inked blue. The epididymis is 5.6 x 1.0 x 0.6 cm. The tunica vaginalis strips with ease. The tunica albuginea is gray-white and smooth.

The testicle is bi-valved to show a tan-brown tumor mass almost entirely replacing the testicular parenchyma. There is only small rim of grossly normal testis identified at the lower pole of the testicle. The tumor has a central white distinct nodule measuring 1.7 x 1.5 x 1 cm. The tumor is abutting and pushing against the tunica albuginea but is grossly not invading. The tumor is located 8.0 cm from the spermatic cord margin, 0.1 cm from the tunica vaginalis and its adjacent tunica albuginea. The seminiferous tubules are tan-orange.

Representative sections are submitted as follows:

Cassette 1. Upper spermatic cord margin

Cassette 2. Middle spermatic cord margin

Cassette A3. Lower spermatic cord margin

Cassette A4-A12. Tumor to includes tunica vaginalis, seminiferous tubules, rete testis and epididymis

Cassette 12. Additional section of tumor

Cassette A13. Interface of the rim of normal testis and tumor, grossly normal seminiferous tubules

Cassette A14: normal testis

Pathology Resident

Microscopic Description

Right testicular mass is a mixed germ cell tumor, mostly consistent of classic type seminoma and mature teratoma with hyaline cartilage. Seminoma tumor cells are staining with c-kit. The tumor is confined to the testicle with no lymphovascular or perineural invasion. Focally, ITGCN and atrophy are seen.

This case was reviewed by the staff pathologist listed below.

****Electronically Signed Out****

Staff Pathologist

Source: NCI Genomic Data Commons file 0c0a2836-004e-468a-b440-9f786f7c0ba6 (TCGA-SN-A6IS.8B806C09-DCC2-4BD0-90D4-B91C6D214B2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).